Surgical pathology report (de-identified scan), TCGA case TCGA-22-4605, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-4605-01A (Primary Tumor).

[REDACTED] Surgical Pathology

TISSUE DESCRIPTION:

Right upper lobe lung (17.5 x 12.5 x 4.3 cm), superior (right upper and lower paratracheal, right tracheobronchial) and inferior (subcarinal, paraesophageal) mediastinal lymph nodes

DIAGNOSIS:

Lung, right upper lobe, lobectomy: Invasive grade 2 (of 4) squamous cell carcinoma forming a mass measuring 4.4 x 2.9 x 1.9 cm which extends into the pleura, but does not involve the adjacent skeletal muscle and soft tissue. The bronchial margin is negative for tumor.

Multiple lymph nodes (2 of 2 intraparenchymal and 4 of 4 intrapulmonary peribronchial) are negative for tumor.

Lymph nodes, superior and inferior mediastinal, excision: Multiple superior (21 right lower paratracheal, 2 right tracheobronchial) and inferior (11 subcarinal) mediastinal lymph nodes are negative for tumor. Tissue submitted as right upper paratracheal lymph node shows vein wall and tissue submitted as paraesophageal lymph node shows fibrovascular tissue; negative for tumor.

Source: NCI Genomic Data Commons file 73a84b39-f708-421e-b3ae-39d9b9b5c6cb (TCGA-22-4605.6D8491DF-72B3-46F8-96B4-016D8662EB15.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).